Somatic mutation profile of tumor specimen TCGA-09-0369-01A (aliquot TCGA-09-0369-01A-01W-0372-09) from TCGA case TCGA-09-0369, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.7 years (20,705 days).
Specimen TCGA-09-0369-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 401ad139-4ba9-4875-a5ad-5521effce945.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-0369-10C (Blood Derived Normal), aliquot TCGA-09-0369-10C-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd0aad5c-494d-4ded-8270-d916904a717e

The open-access MAF lists 86 somatic variants for this specimen: 69 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 16, Nonsense Mutation 5, Splice Site 2, Frame Shift Ins 2, 3'Flank 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TBX6 | c.704dup p.M236Hfs*44 | Frame Shift Ins (INS) | VAF 12/74 reads (16%) | catalogued as rs758051786; ClinVar: pathogenic; called by mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 133/146 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABHD1 | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 55/271 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99574347; called by muse, varscan2
- ABL2 | c.1843C>T p.Q615* (on ENST00000502732 / NM_007314.4; = p.Q600* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 22/291 reads (8%) | catalogued as COSV100772534; called by muse, mutect2
- ACBD4 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as rs1345554276, COSV58851391; called by muse, mutect2, varscan2
- ADAMTS14 | c.1121G>A p.G374D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100941953, COSV64601045; called by muse, mutect2, varscan2
- AL121899.2 | c.153G>T p.L51F | Missense Mutation (SNP) | VAF 80/746 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV101198408; called by muse, mutect2, varscan2
- AMD1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 8/207 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.05); catalogued as rs1349798699, COSV64387445; called by muse, mutect2
- ANO2 | c.606A>C p.K202N (on ENST00000356134 / NM_001278597.3; = p.K206N on NM_001278596.3) | Missense Mutation (SNP) | VAF 326/692 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59015586; called by muse, mutect2, varscan2
- AOC2 | c.1894C>T p.Q632* (on ENST00000253799 / NM_009590.4; = p.Q605* on NM_001158.5) | Nonsense Mutation (SNP) | VAF 63/144 reads (44%) | catalogued as rs970881126, COSV53825593; called by muse, mutect2, varscan2
- AOX1 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 25/394 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.049); catalogued as COSV101021801; called by muse, mutect2
- AP1M1 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as rs372560384, COSV52225827; called by muse, mutect2, varscan2
- ATG2A | c.923A>T p.D308V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV65966294; called by muse, mutect2
- ATP6V1D | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 117/301 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as rs771168394, COSV53599217, COSV99371030; called by muse, mutect2, varscan2
- CAD | c.2467G>C p.V823L | Missense Mutation (SNP) | VAF 58/292 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV53025299; called by muse, mutect2, varscan2
- CCNB1IP1 | c.504T>A p.N168K | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV62302603; called by muse, mutect2, varscan2
- CELSR3 | c.2245G>A p.V749I | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs145148789; called by muse, mutect2, varscan2
- CERS3 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 116/144 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767763454, COSV52566792; called by muse, mutect2, varscan2
- CLGN | c.545C>G p.P182R | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57773946; called by muse, mutect2, varscan2
- CNTN5 | c.885G>A p.M295I | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV99039342, COSV99673929, COSV99676860; called by muse, mutect2
- CRYBG1 | c.3061C>T p.L1021F | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.308); catalogued as COSV64811561; called by muse, mutect2, varscan2
- CSMD1 | c.9575C>G p.S3192C (on ENST00000520002; = p.S3191C on NM_033225.6) | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59304948; called by muse, mutect2, varscan2
- CSN3 | c.179C>A p.T60N | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.113); catalogued as rs761442017, COSV59243829; called by muse, mutect2, varscan2
- E2F5 | c.941T>A p.L314H | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56274425; called by muse, mutect2
- ETNK2 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as rs751988639, COSV65820560; called by muse, mutect2, varscan2
- FEZF1 | c.675G>C p.Q225H | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV58658470; called by muse, mutect2, varscan2
- GCHFR | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53066782; called by muse, mutect2, varscan2
- GHDC | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1472737257, COSV56989689; called by muse, mutect2
- GJA1 | c.865G>C p.V289L | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV56997507; called by muse, mutect2, varscan2
- GNA12 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 56/105 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV51739921; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1123G>A p.V375M | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56085726; called by muse, mutect2, varscan2
- HENMT1 | c.313A>C p.N105H | Missense Mutation (SNP) | VAF 84/188 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV64230059; called by muse, mutect2, varscan2
- HIVEP2 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV99171564; called by muse, mutect2, varscan2
- IL18RAP | c.794T>A p.L265H | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51825243; called by muse, varscan2
- LAMB4 | c.4480G>C p.V1494L | Missense Mutation (SNP) | VAF 123/304 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as COSV52716821, COSV99224244; called by muse, mutect2, varscan2
- LAMC3 | c.2440G>A p.G814R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as rs529385350, COSV100736074, COSV63089922; called by muse, mutect2, varscan2
- LRRK2 | c.2855T>C p.I952T | Missense Mutation (SNP) | VAF 124/210 reads (59%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV54149107; called by muse, mutect2, varscan2
- MRAS | c.407T>G p.I136S | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV56670969; called by muse, mutect2, varscan2
- MYCN | c.1073C>T p.P358L | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.071); catalogued as rs775092426, COSV55258248; called by muse, mutect2, varscan2
- MYF5 | c.577+2T>G p.X193_splice | Splice Site (SNP) | VAF 79/242 reads (33%) | catalogued as COSV57354819; called by muse, varscan2
- NME8 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 107/165 reads (65%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV52248684; called by muse, mutect2, varscan2
- OR10A7 | c.695C>T p.T232I | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as COSV58278104; called by muse, mutect2, varscan2
- PCDHB11 | c.1090G>A p.V364M | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.826); catalogued as rs1554285402, COSV61310690; called by muse, mutect2, varscan2
- PDZD2 | c.1656T>G p.S552R | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV56855280; called by muse, mutect2, varscan2
- PSENEN | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53074314; called by muse, mutect2, varscan2
- PZP | c.266C>T p.T89I | Missense Mutation (SNP) | VAF 57/276 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV54357605; called by muse, mutect2, varscan2
- SCN9A | c.3358A>T p.N1120Y (on ENST00000303354; = p.N1109Y on NM_002977.3) | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV57605636; called by muse, mutect2, varscan2
- SF3B3 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV100209640; called by muse, mutect2
- SLC1A7 | c.1414A>T p.I472F | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57012395; called by muse, mutect2, varscan2
- SOS2 | c.3733G>A p.D1245N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.135); catalogued as COSV99365546; called by muse, mutect2
- STX1B | c.852dup p.T285Dfs*75 | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | catalogued as rs762705451; called by pindel, varscan2
- SUMF2 | c.802C>T p.R268C (on ENST00000652303; = p.P297L on NM_015411.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs767327111, COSV51915755; called by muse, mutect2
- SZT2 | c.4807G>A p.V1603I (on ENST00000634258 / NM_001365999.1; = p.V1546I on NM_015284.4) | Missense Mutation (SNP) | VAF 70/143 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV65168634; called by muse, mutect2, varscan2
- TRA2A | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 44/183 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV51716426; called by muse, mutect2, varscan2
- TRAF2 | c.802C>T p.L268F | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.27); catalogued as COSV56037255; called by muse, mutect2, varscan2
- TRAF3IP3 | c.915+1G>T p.X305_splice | Splice Site (SNP) | VAF 59/255 reads (23%) | catalogued as COSV50551708; called by muse, mutect2, varscan2
- TTN | c.39305G>T p.G13102V (on ENST00000591111; = p.G5678V on NM_003319.4) | Missense Mutation (SNP) | VAF 98/113 reads (87%) | PolyPhen benign (0.011); catalogued as COSV59974093; called by muse, mutect2, varscan2
- UBR5 | c.6659T>A p.V2220E | Missense Mutation (SNP) | VAF 26/307 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99639754; called by muse, mutect2
- VAV2 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.222); catalogued as rs199806132, COSV64081164; called by muse, mutect2
- ZNF133 | c.1418G>T p.R473L (on ENST00000316358 / NM_001352454.2; = p.R472L on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 166/451 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100315454; called by muse, varscan2
- ZNF274 | c.931G>T p.E311* (on ENST00000610905; = p.E206* on NM_016324.3) | Nonsense Mutation (SNP) | VAF 67/493 reads (14%) | catalogued as COSV100464814, COSV58763555; called by muse, mutect2, varscan2
- ZNF512 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV100820698; called by muse, mutect2, varscan2
- ANGEL1 | c.1377G>A p.W459* | Nonsense Mutation (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- FBXO27 | c.570C>G p.D190E | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.153); called by muse, mutect2
- FRMPD2 | c.3283C>A p.Q1095K | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- GLOD4 | c.517C>G p.L173V (on ENST00000301328 / NM_001366247.1; = p.L158V on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/374 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.53); called by muse, mutect2
- MAGEA4 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.455); called by muse, mutect2
- TTLL9 | c.1317_*7del | Nonstop Mutation (DEL) | VAF 48/417 reads (12%) | called by pindel, varscan2
- ZFC3H1 | c.1541A>C p.Q514P | Missense Mutation (SNP) | VAF 10/297 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- ADCY3 | c.3159C>T p.V1053= | Silent (SNP) | VAF 14/136 reads (10%) | catalogued as rs907824331, COSV99567813; called by muse, mutect2
- AMER1 | c.2631C>T p.G877= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV57658221; called by muse, mutect2, varscan2
- ATXN2L | c.816C>T p.S272= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as COSV100293894; called by muse, mutect2, varscan2
- CDH10 | c.2082G>A p.T694= | Silent (SNP) | VAF 55/171 reads (32%) | catalogued as COSV52576436; called by muse, mutect2, varscan2
- CYFIP1 | c.1758G>A p.G586= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as rs1024344678; called by mutect2, varscan2
- DBF4B | c.1644C>T p.L548= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as COSV100154343; called by muse, mutect2
- DLGAP2 | c.1041C>T p.N347= | Silent (SNP) | VAF 49/80 reads (61%) | catalogued as rs759975919, COSV70096666, COSV70097456; called by muse, mutect2, varscan2
- ILKAP | c.660G>A p.T220= | Silent (SNP) | VAF 31/71 reads (44%) | catalogued as rs150186666, COSV54517839; called by muse, mutect2, varscan2
- ITGAX | c.1017G>A p.T339= | Silent (SNP) | VAF 35/103 reads (34%) | catalogued as rs751433732, COSV51641197, COSV51641897; called by muse, mutect2, varscan2
- NCOA3 | c.1701C>T p.S567= | Silent (SNP) | VAF 25/397 reads (6%) | called by muse, mutect2
- NSD2 | c.4000A>C p.R1334= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as COSV56389009; called by muse, mutect2, varscan2
- PIP4P1 | c.231G>A p.G77= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99164448; called by muse, mutect2, varscan2
- SAMM50 | c.723G>A p.T241= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as rs766140123, COSV63110184; called by muse, mutect2, varscan2
- SIGLEC5 | c.837G>A p.L279= | Silent (SNP) | VAF 8/143 reads (6%) | called by muse, mutect2
- SLC2A9 | c.1083G>T p.G361= | Silent (SNP) | VAF 43/176 reads (24%) | catalogued as rs1432915400, COSV53316233; called by muse, mutect2, varscan2
- SNX15 | c.153G>T p.R51= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as COSV57246431; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792079 C>A | 3'Flank (SNP) | VAF 36/51 reads (71%) | called by muse, mutect2, varscan2
